Gene-level copy-number profile of tumor specimen TCGA-CV-7406-01A from TCGA case TCGA-CV-7406, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 50.0 years (18,250 days).
Specimen TCGA-CV-7406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e660a164-c71d-44d4-b447-eecfea9b259e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7406-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1cdc6a0f-3192-40a3-9dbf-e6a6355a3ae9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,147; copy number 2: 40,092; copy number 3: 6,159; copy number 4: 1,961; copy number 5: 7; copy number 6: 345; copy number 7: 11; copy number 9: 15; copy number 12: 83.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7406-01A-11D-2077-01): tumor purity 0.6, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 461 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:29,407,100–34,039,914, 27 genes, copy number 6–9: AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1.
- chr4:34,140,598–34,180,729, 1 gene, copy number 7: AC110790.1.
- chr12:6,477,714–12,267,044, 290 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:26,599,755–27,845,286, 7 genes, copy number 5 (within-gene range 1–5): AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1.
- chr14:48,194,174–53,948,484, 136 genes, copy number 6–12 (within-gene range 1–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
